TARGET case TARGET-40-PAIWEV — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/df83f108-764d-5726-8e2c-6311ebf3fa5e

Demographics
Sex at birth: male; Race: black or african american; Age at index: 16 years; Vital status: Dead; Days to death: 750 days (2.1 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 16.5 years (6,025 days); Year of diagnosis: 1999; Metastasis at diagnosis: No Metastasis; Days to last follow up: 750 days (2.1 years).
   Pathology details: Necrosis percent: 20.
   Treatment given: Protocol identifier: P9754.

Follow-up (2 entries)
- Days to follow up: 609 days (1.7 years); Progression or recurrence: Yes; Days to progression: 609 days (1.7 years); Days to first event: 609 days (1.7 years); First event: Relapse.
- Days to follow up: 750 days (2.1 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2001.

Biospecimens (1 sample)
- Sample TARGET-40-PAIWEV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PAIWEV-01A:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 95
- % Non Tumor Nuclei: Top from Biopsy: 5
- % Cellular Tumor: Top from Biopsy: 86
- % Normal: Top from Biopsy: 7
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 7
- % Tumor Nuclei: Bottom from Biopsy: 97
- % Non Tumor Nuclei: Bottom from Biopsy: 3
- % Cellular Tumor: Bottom from Biopsy: 85
- % Normal: Bottom from Biopsy: 5
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 10
- PASS/FAIL: PASS

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 750
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: Yes
